Somatic mutation profile of tumor specimen TCGA-LN-A49O-01A (aliquot TCGA-LN-A49O-01A-11D-A247-09) from TCGA case TCGA-LN-A49O, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 47.2 years (17,237 days).
Specimen TCGA-LN-A49O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74abe75b-a2f0-431e-aae8-177850210e70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49O-10A (Blood Derived Normal), aliquot TCGA-LN-A49O-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a8f1e7c-f037-45fa-8852-7d11d38831a6

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Frame Shift Ins 5, Nonsense Mutation 3, Intron 3, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 21/27 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2842C>T p.R948* (on ENST00000404938 / NM_001163941.2; = p.R503* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs1158560751, COSV51705757; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as rs745841113, CM104797; called by muse, mutect2
- ARHGAP31 | c.537C>G p.L179= | Splice Region (SNP) | VAF 18/45 reads (40%) | catalogued as rs1245098567, COSV51800606; called by muse, mutect2, varscan2
- CDH13 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs776340601, COSV51827799; called by muse, mutect2, varscan2
- CHST5 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1012780061, COSV60339864; called by muse, mutect2, varscan2
- CSF1R | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV53827575; called by muse, mutect2, varscan2
- FRMD1 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs767627123; called by muse, mutect2, varscan2
- JRK | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs369670710; called by muse, mutect2, varscan2
- MORC1 | c.2015G>C p.R672T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs749399375; called by muse, mutect2, varscan2
- NCOR2 | c.5008A>G p.I1670V | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs772634427; called by muse, mutect2, varscan2
- NHSL2 | c.733C>G p.H245D (on ENST00000510661; = p.H611D on NM_001013627.2) | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV65454554; called by muse, mutect2, varscan2
- OR11H4 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs758843352; called by muse, mutect2, varscan2
- OR14A16 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV100713723; called by mutect2, varscan2
- OR2A4 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59575736; called by muse, mutect2, varscan2
- PCDH15 | c.1985A>G p.N662S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.475); catalogued as rs373731707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA2 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1269275813, COSV65437873; called by muse, mutect2, varscan2
- RAI1 | c.5398G>A p.D1800N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs777865239, COSV55392643; called by muse, mutect2, varscan2
- SCN11A | c.4978G>A p.A1660T | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs564668486; called by muse, mutect2, varscan2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by muse, mutect2
- SLC15A2 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757477203; called by muse, mutect2, varscan2
- SLC7A11 | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV99763143; called by muse, mutect2, varscan2
- WNT5B | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.244); catalogued as rs774388139; called by muse, mutect2, varscan2
- ZNF804B | c.1088C>A p.A363E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1256051194, COSV100301737; called by muse, mutect2, varscan2
- ADRA2A | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATF4 | c.160dup p.A54Gfs*2 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- CECR2 | c.1098G>T p.K366N (on ENST00000342247 / NM_001290047.2; = p.K203N on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNOT1 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF16 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSE | c.562A>T p.M188L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- FILIP1 | c.1226A>G p.K409R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FOXJ2 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- GRAMD2B | c.977C>A p.S326* | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- GRHL2 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPNA4 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCN1 | c.196A>T p.N66Y | Missense Mutation (SNP) | VAF 87/117 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MFN1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MGAT3 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); called by muse, mutect2
- MUL1 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- NFATC2 | c.314_315insT p.A106Gfs*66 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- NSUN4 | c.758dup p.V254Gfs*14 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- PHOSPHO2 | c.384dup p.N129* | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.111A>G p.I37M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PREX1 | c.4204A>G p.T1402A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RHOBTB1 | c.1232T>C p.F411S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RLF | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RNF213 | c.14898G>T p.Q4966H | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SCAPER | c.464A>T p.E155V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by mutect2, varscan2
- SNX7 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- STARD10 | c.578-2A>G p.X193_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- SYMPK | c.1742C>A p.A581E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- TRRAP | c.5411C>A p.P1804Q (on ENST00000359863 / NM_001244580.1; = p.P1786Q on NM_003496.3) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- UBIAD1 | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UTP4 | c.494dup p.D166Rfs*4 | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- ZNF709 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF750 | c.200_233del p.K67Sfs*288 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- AC013489.1 | c.582T>C p.H194= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs1406719669; called by muse, mutect2, varscan2
- ARRDC2 | c.402C>A p.T134= | Silent (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- CDON | c.855C>A p.S285= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV54994973; called by muse, mutect2, varscan2
- COLGALT1 | c.1746C>T p.V582= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- GMEB1 | c.831G>A p.Q277= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs761435111; called by muse, mutect2, varscan2
- HDLBP | c.2565T>C p.C855= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- KDM4B | c.1854G>A p.P618= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs755937200; called by muse, mutect2, varscan2
- KIFC3 | c.321A>G p.E107= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- NTM | c.888G>T p.V296= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- OR8H3 | c.315C>G p.V105= | Silent (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2322C>T p.F774= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as rs782811619, COSV50566253, COSV50575056; called by muse, mutect2, varscan2
- PI16 | c.258C>T p.G86= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs770111668; called by muse, mutect2, varscan2
- PSKH2 | c.1149G>A p.A383= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs773303354; called by muse, mutect2, varscan2
- RNF31 | c.1467C>T p.L489= | Silent (SNP) | VAF 36/44 reads (82%) | called by muse, mutect2, varscan2
- SAFB | c.2073C>T p.R691= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- UCKL1 | c.1041C>T p.R347= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV62402650; called by muse, mutect2, varscan2
- ZNF221 | c.429C>T p.S143= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- CASP2 | c.967+91A>G | Intron (SNP) | VAF 22/32 reads (69%) | catalogued as rs763709140; called by muse, mutect2, varscan2
- MOG | c.593-88A>G | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- STRN3 | c.282+11252C>A | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs1214688306, COSV62578594; called by muse, mutect2
